Somatic mutation profile of tumor specimen TCGA-X6-A7W8-01A (aliquot TCGA-X6-A7W8-01A-21D-A351-09) from TCGA case TCGA-X6-A7W8, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Fibromyxosarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-X6-A7W8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e17146ac-df46-4e63-9d6c-76d302ae5dab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-X6-A7W8-10A (Blood Derived Normal), aliquot TCGA-X6-A7W8-10A-01D-A351-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/edd996a8-842b-4873-9665-4db6e084c85e

The open-access MAF lists 70 somatic variants for this specimen: 47 protein-altering or splice-affecting, 19 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 19, Frame Shift Del 3, RNA 2, Nonsense Mutation 2, 5'Flank 1, Intron 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYH7 | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.372); catalogued as rs730880832, COSV100806162; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABHD2 | c.1233G>T p.K411N | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); catalogued as COSV100756304; called by muse, mutect2
- AGR2 | c.428G>T p.G143V | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101290819; called by muse, mutect2, varscan2
- ANKEF1 | c.1896G>T p.K632N | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.206); catalogued as COSV101001026; called by muse, mutect2, varscan2
- ATP8A2 | c.3097G>A p.G1033R | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768202781, COSV99682201; called by muse, mutect2, varscan2
- CCL3 | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 29/210 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as rs773703371; called by muse, mutect2, varscan2
- CD200 | c.800G>T p.S267I (on ENST00000473539 / NM_001004196.3; = p.S242I on NM_005944.7 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/74 reads (57%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV100238345; called by muse, mutect2, varscan2
- CD22 | c.2136G>C p.W712C | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV50052894, COSV99323280; called by muse, mutect2, varscan2
- CFTR | c.1508A>G p.K503R | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.65); PolyPhen benign (0.157); catalogued as COSV99136564; called by muse, mutect2, varscan2
- CHD5 | c.2753A>T p.K918M | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99313763; called by muse, mutect2, varscan2
- CTRC | c.256G>A p.V86M | Missense Mutation (SNP) | VAF 40/56 reads (71%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as rs367979183; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DDX46 | c.391A>G p.K131E | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.82); PolyPhen benign (0.026); catalogued as rs1190340316, COSV100844883; called by muse, mutect2, varscan2
- DNAH2 | c.1548C>G p.Y516* | Nonsense Mutation (SNP) | VAF 23/62 reads (37%) | catalogued as COSV99317758, COSV99318231; called by muse, mutect2, varscan2
- DOCK11 | c.351C>A p.Y117* | Nonsense Mutation (SNP) | VAF 88/140 reads (63%) | catalogued as COSV99353940; called by muse, varscan2
- EML5 | c.4083G>T p.E1361D (on ENST00000380664; = p.E1369D on NM_183387.3) | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.755); catalogued as COSV100715698; called by muse, mutect2, varscan2
- ESR2 | c.1025G>A p.G342E | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs553390407, COSV99963324; called by muse, mutect2, varscan2
- FAT2 | c.4354C>T p.R1452C | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.174); catalogued as rs976684323, COSV55821902; called by muse, mutect2, varscan2
- GAR1 | c.527G>A p.R176Q | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.003); catalogued as rs1158226770, COSV99901913; called by muse, mutect2, varscan2
- IL25 | c.326G>A p.R109H | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as rs767430645, COSV59306825; called by muse, mutect2, varscan2
- KIF4A | c.1955G>A p.R652H | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.066); catalogued as rs35473790, COSV65541997; called by muse, mutect2, varscan2
- KLK9 | c.592G>T p.G198C | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99143990; called by muse, mutect2, varscan2
- LHFPL1 | c.308T>C p.V103A | Missense Mutation (SNP) | VAF 42/47 reads (89%) | SIFT tolerated (0.3); PolyPhen benign (0.135); catalogued as rs1436760854, COSV100914470; called by muse, mutect2, varscan2
- MAGEB16 | c.451T>A p.F151I | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV101303307; called by muse, mutect2, varscan2
- MUC16 | c.7178C>T p.P2393L | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); catalogued as COSV101200035; called by muse, mutect2, varscan2
- MUC6 | c.4135C>G p.Q1379E | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as COSV101424612; called by muse, mutect2, varscan2
- OR6X1 | c.259A>G p.R87G | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV60009576, COSV60010048; called by muse, mutect2, varscan2
- PAX9 | c.980A>G p.Q327R | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); catalogued as COSV100491379; called by muse, mutect2, varscan2
- PIK3R3 | c.109C>A p.L37I | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.051); catalogued as COSV53110478, COSV99422216; called by muse, mutect2, varscan2
- PRLR | c.848T>A p.L283Q | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99184431; called by muse, mutect2, varscan2
- RAB3GAP2 | c.2277G>T p.L759F | Missense Mutation (SNP) | VAF 22/30 reads (73%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); catalogued as COSV100741289; called by muse, mutect2, varscan2
- SCO1 | c.694G>C p.E232Q | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); catalogued as COSV99703554; called by muse, mutect2, varscan2
- SEMA3C | c.2158G>C p.D720H | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV99543094; called by muse, mutect2, varscan2
- SFXN1 | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV100369340; called by muse, mutect2, varscan2
- SLC22A2 | c.352C>T p.P118S | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.687); catalogued as COSV100870988; called by muse, mutect2, varscan2
- SLC5A10 | c.906C>G p.I302M | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100525168; called by muse, varscan2
- SPAM1 | c.913C>T p.R305C | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747607749, COSV56143286, COSV56143381; called by muse, mutect2, varscan2
- TECTA | c.6394G>T p.V2132F | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.11); catalogued as COSV99880035; called by muse, mutect2, varscan2
- TMEM163 | c.535A>C p.T179P | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.885); catalogued as COSV99926414; called by muse, mutect2, varscan2
- TMEM67 | c.2902C>G p.Q968E | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.604); catalogued as COSV100019378; called by muse, mutect2, varscan2
- VEZT | c.1833C>T p.A611= | Splice Region (SNP) | VAF 18/67 reads (27%) | catalogued as rs529936457, COSV54138549; called by muse, mutect2, varscan2
- ZNF215 | c.1285C>A p.H429N | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV53492630, COSV99549655; called by muse, mutect2, varscan2
- ZNF536 | c.683C>T p.P228L | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.13); PolyPhen benign (0.022); catalogued as rs759997778, COSV100835282; called by muse, mutect2, varscan2
- CABIN1 | c.1874_1884+9del p.X625_splice | Splice Site (DEL) | VAF 10/40 reads (25%) | called by mutect2, pindel, varscan2
- FAT3 | c.3957del p.F1319Lfs*9 | Frame Shift Del (DEL) | VAF 23/42 reads (55%) | called by mutect2, pindel, varscan2
- GOLGA2 | c.573del p.E192Nfs*9 | Frame Shift Del (DEL) | VAF 45/119 reads (38%) | called by mutect2, pindel, varscan2
- LRRC40 | c.1293C>A p.N431K | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2
- MME | c.526del p.Q176Kfs*16 | Frame Shift Del (DEL) | VAF 10/49 reads (20%) | called by mutect2, pindel, varscan2
- AGXT2 | c.654T>A p.P218= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as COSV99183762; called by muse, mutect2, varscan2
- CCKAR | c.984C>A p.P328= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as rs1295224668, COSV99810304; called by muse, mutect2
- CDH12 | c.270A>G p.K90= | Silent (SNP) | VAF 88/248 reads (35%) | catalogued as COSV101202657; called by muse, mutect2, varscan2
- EFCAB12 | c.519C>A p.R173= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as COSV100394637; called by muse, mutect2, varscan2
- ESYT2 | c.2256G>A p.P752= (on ENST00000613624; = p.P676= on NM_020728.3) | Silent (SNP) | VAF 16/30 reads (53%) | catalogued as rs771464234, COSV51750227; called by muse, mutect2, varscan2
- EXD3 | c.387C>T p.F129= | Silent (SNP) | VAF 22/81 reads (27%) | catalogued as COSV100573740; called by muse, mutect2, varscan2
- GBA | c.1449G>A p.L483= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as rs1418225952, COSV100516351; called by muse, mutect2, varscan2
- GRIN3A | c.726A>G p.L242= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV100701536; called by muse, mutect2, varscan2
- HAVCR2 | c.252A>G p.L84= | Silent (SNP) | VAF 19/56 reads (34%) | catalogued as COSV100324783; called by muse, mutect2, varscan2
- LRP2 | c.12111G>T p.T4037= | Silent (SNP) | VAF 16/101 reads (16%) | catalogued as rs745582154, COSV55558718, COSV99788683; called by muse, mutect2, varscan2
- RARS2 | c.1284G>T p.G428= | Silent (SNP) | VAF 37/50 reads (74%) | catalogued as COSV101057295; called by muse, mutect2, varscan2
- SLCO2B1 | c.1668G>A p.T556= | Silent (SNP) | VAF 14/20 reads (70%) | catalogued as rs773751583, COSV56939836; called by muse, mutect2, varscan2
- SPEN | c.10809G>C p.L3603= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as COSV100999020; called by muse, mutect2, varscan2
- TCAIM | c.789A>G p.A263= | Silent (SNP) | VAF 31/43 reads (72%) | catalogued as COSV100703282; called by muse, mutect2, varscan2
- TNFRSF11B | c.243A>G p.L81= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV99816698; called by muse, mutect2, varscan2
- TOM1L2 | c.939C>T p.S313= (on ENST00000379504 / NM_001350333.2; = p.S263= on NM_001033551.3) | Silent (SNP) | VAF 12/144 reads (8%) | catalogued as rs1223307613, COSV100541056; called by muse, mutect2
- TRHDE | c.1440C>A p.G480= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV99671031; called by muse, mutect2, varscan2
- UNC13C | c.4239T>C p.Y1413= | Silent (SNP) | VAF 13/80 reads (16%) | catalogued as COSV99518058; called by muse, mutect2, varscan2
- WNK2 | c.6795C>T p.P2265= | Silent (SNP) | VAF 29/65 reads (45%) | catalogued as COSV99942665; called by muse, mutect2, varscan2
- ARIH2 | chr3:48918479 del GGGGTGTAG | 5'Flank (DEL) | VAF 17/112 reads (15%) | called by mutect2, pindel, varscan2
- MGLL | c.233-13246C>A | Intron (SNP) | VAF 5/50 reads (10%) | catalogued as COSV99411924; called by muse, mutect2
- MIR646 | n.83A>T | RNA (SNP) | VAF 7/83 reads (8%) | called by muse, mutect2
- REXO1L1P | n.1511C>T | RNA (SNP) | VAF 29/262 reads (11%) | catalogued as rs766693941; called by muse, varscan2
